Somatic mutation profile of tumor specimen TCGA-AA-A01S-01A (aliquot TCGA-AA-A01S-01A-21W-A096-10) from TCGA case TCGA-AA-A01S, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage III; Age at diagnosis: 47.2 years (17,257 days).
Specimen TCGA-AA-A01S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08fbff91-8e7f-4db0-afcb-79e26af7c958.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01S-11A (Solid Tissue Normal), aliquot TCGA-AA-A01S-11A-21W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cd8770b-c22b-49f4-b9e5-6049e158ff67

The open-access MAF lists 64 somatic variants for this specimen: 45 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 37, Silent 19, Nonsense Mutation 6, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 37/86 reads (43%) | catalogued as rs876660802, CM105717, COSV57324327; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 263/746 reads (35%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 80/99 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 104/369 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100313017, COSV61658469; called by muse, mutect2, varscan2
- ALDH5A1 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62373923; called by muse, mutect2, varscan2
- BRINP1 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs764143707, COSV56299499; called by muse, mutect2, varscan2
- C1orf94 | c.1008G>A p.M336I (on ENST00000488417 / NM_001134734.2; = p.M146I on NM_032884.5) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs747441377, COSV64915433; called by muse, mutect2, varscan2
- CDH23 | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as rs763352314, COSV54937697; called by muse, mutect2, varscan2
- CEP55 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 122/308 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.691); catalogued as COSV65185318; called by muse, mutect2, varscan2
- CFAP47 | c.5503C>A p.L1835I | Missense Mutation (SNP) | VAF 307/831 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.455); catalogued as COSV100545671; called by muse, mutect2, varscan2
- CNTN6 | c.2152G>A p.V718I | Missense Mutation (SNP) | VAF 176/414 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs140014929, COSV63183796; called by muse, mutect2, varscan2
- COL3A1 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 171/338 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV58598325; called by muse, mutect2, varscan2
- CPQ | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 229/343 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs753340797, COSV55140372; called by muse, mutect2, varscan2
- CSTL1 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 329/554 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55677714, COSV55678590; called by muse, mutect2, varscan2
- DPP8 | c.628A>G p.S210G (on ENST00000341861 / NM_001320875.2; = p.S194G on NM_017743.6) | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.101); catalogued as COSV100202596; called by muse, mutect2, varscan2
- ENY2 | c.154+2T>C p.X52_splice | Splice Site (SNP) | VAF 370/1545 reads (24%) | catalogued as COSV60565797; called by muse, mutect2, varscan2
- EXD3 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs368890121; called by muse, mutect2, varscan2
- GHITM | c.1008G>A p.M336I | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111408234, COSV100930130; called by muse, mutect2, varscan2
- HPS6 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs761823678, COSV100154987; called by muse, mutect2, varscan2
- IGF2BP1 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV51733432; called by muse, mutect2, varscan2
- KRTAP11-1 | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV60094203, COSV60095232; called by muse, mutect2, varscan2
- MCHR2 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 221/590 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs199970126; called by muse, varscan2
- NKAPL | c.778T>G p.L260V | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.194); catalogued as COSV59198263; called by muse, mutect2, varscan2
- OR2B11 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 115/128 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs764642577, COSV59509708; called by muse, mutect2, varscan2
- OTOL1 | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs370829105; called by muse, mutect2, varscan2
- PHLDB1 | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV100616744; called by muse, mutect2, varscan2
- PIWIL3 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 303/664 reads (46%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.682); catalogued as rs779523659, COSV59996320; called by muse, mutect2, varscan2
- PKN1 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs1189842712, COSV99466624; called by muse, mutect2, varscan2
- PXMP2 | c.567C>A p.Y189* | Nonsense Mutation (SNP) | VAF 71/164 reads (43%) | catalogued as COSV58095605; called by muse, mutect2, varscan2
- RBBP8NL | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs751817374, COSV99436938; called by muse, mutect2, varscan2
- SEPHS1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100526011; called by muse, mutect2, varscan2
- SH3GL3 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); catalogued as COSV61061303; called by muse, mutect2, varscan2
- SHC4 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60114528; called by muse, mutect2, varscan2
- SLC12A1 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 206/506 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100372538; called by muse, mutect2, varscan2
- SLC18A3 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.178); catalogued as rs1270138469; called by muse, mutect2
- SLCO1B3 | c.1884A>T p.L628F | Missense Mutation (SNP) | VAF 247/678 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as COSV99682135; called by muse, mutect2, varscan2
- TG | c.7325G>T p.C2442F | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99602831; called by muse, mutect2, varscan2
- TMC1 | c.2230C>T p.R744* | Nonsense Mutation (SNP) | VAF 332/729 reads (46%) | catalogued as rs150738413, COSV52785229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNFRSF11B | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.613); catalogued as rs201167408, COSV99816910; called by muse, mutect2, varscan2
- TTLL9 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 124/201 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201616223, COSV60596963; called by muse, mutect2, varscan2
- TTN | c.43760G>A p.R14587H (on ENST00000591111; = p.R7163H on NM_003319.4) | Missense Mutation (SNP) | VAF 137/526 reads (26%) | PolyPhen probably damaging (0.998); catalogued as rs368806005; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TUBG2 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 35/143 reads (24%) | catalogued as rs768619979, COSV52218283; called by muse, mutect2, varscan2
- UNC5C | c.240C>G p.N80K | Missense Mutation (SNP) | VAF 219/506 reads (43%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.954); catalogued as COSV101498011; called by muse, mutect2, varscan2
- UQCRC1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52552179; called by muse, mutect2, varscan2
- ORM2 | c.207del p.F69Lfs*29 | Frame Shift Del (DEL) | VAF 43/140 reads (31%) | called by mutect2, varscan2
- ADAM29 | c.2316G>T p.V772= | Silent (SNP) | VAF 77/187 reads (41%) | catalogued as COSV63664816; called by muse, mutect2, varscan2
- C3 | c.2718C>T p.G906= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as COSV55575315; called by muse, mutect2, varscan2
- CDH4 | c.1554G>A p.E518= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV64660161; called by muse, mutect2, varscan2
- CHRNA4 | c.732C>G p.L244= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs752054605, COSV64720112; called by muse, mutect2, varscan2
- CNNM1 | c.1791G>A p.S597= | Silent (SNP) | VAF 79/227 reads (35%) | catalogued as rs369793453; called by muse, mutect2, varscan2
- ERAP2 | c.2166C>A p.L722= | Silent (SNP) | VAF 71/147 reads (48%) | catalogued as COSV101163782, COSV65940210; called by muse, mutect2, varscan2
- FBN1 | c.5382A>G p.P1794= | Silent (SNP) | VAF 202/493 reads (41%) | catalogued as rs777460910, COSV57320813; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.18G>A p.R6= | Silent (SNP) | VAF 68/393 reads (17%) | catalogued as rs747497403; called by muse, mutect2, varscan2
- JARID2 | c.837G>A p.S279= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs142545160; called by muse, mutect2, varscan2
- LRRC37A3 | c.1110T>C p.S370= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs750287799, COSV59762095; called by mutect2, varscan2
- MOS | c.381G>A p.T127= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV61336517; called by muse, mutect2, varscan2
- PCDHGA8 | c.1605C>T p.S535= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV53971998; called by muse, mutect2, varscan2
- PIAS1 | c.402G>A p.P134= | Silent (SNP) | VAF 154/440 reads (35%) | catalogued as rs756448930, COSV51031223; called by muse, mutect2, varscan2
- PIAS3 | c.1506G>A p.T502= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV57907101; called by muse, mutect2, varscan2
- PKHD1L1 | c.2415G>A p.G805= | Silent (SNP) | VAF 617/943 reads (65%) | catalogued as COSV65745994; called by muse, mutect2, varscan2
- TFB2M | c.1041G>A p.A347= | Silent (SNP) | VAF 217/241 reads (90%) | catalogued as rs369141918; called by muse, mutect2, varscan2
- TMEM255A | c.27G>T p.R9= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV59029958; called by muse, mutect2, varscan2
- ZFHX3 | c.7083C>T p.D2361= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs767177678, COSV51723274; called by muse, mutect2, varscan2
- ZFP37 | c.1632G>A p.P544= | Silent (SNP) | VAF 111/271 reads (41%) | catalogued as rs138245465; called by muse, mutect2, varscan2
